Somatic mutation profile of tumor specimen ALCH-AFAV-TTP1-A (aliquot ALCH-AFAV-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AFAV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,463 days).
Specimen ALCH-AFAV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0959c4c6-4ca8-4c1e-af14-720c29c2e20b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFAV-NB1-A (Blood Derived Normal), aliquot ALCH-AFAV-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a6bc7ce-5616-444a-b189-6e3d861175b5

The open-access MAF lists 234 somatic variants for this specimen: 163 protein-altering or splice-affecting, 56 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 56, Nonsense Mutation 12, Intron 7, Splice Site 3, 5'UTR 3, RNA 2, Splice Region 2, 3'UTR 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 50/576 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.831T>A p.C277* | Nonsense Mutation (SNP) | VAF 36/500 reads (7%) | hotspot (GDC flag); catalogued as rs1057523347, CM065496, COSV52676368, COSV52783531, COSV53164903; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AKR1B1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 30/439 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV53647140; called by muse, mutect2
- ANGPT4 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV101124698; called by muse, mutect2
- ASCC3 | c.4953G>T p.W1651C | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64974869; called by muse, mutect2
- ASIC4 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.07); catalogued as COSV61731840; called by muse, mutect2, varscan2
- BPTF | c.3157A>G p.T1053A | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1268800059, COSV58843354; called by muse, mutect2
- C4orf51 | c.68T>A p.F23Y | Missense Mutation (SNP) | VAF 24/634 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV71263712; called by muse, mutect2
- CNTN6 | c.2587A>G p.T863A | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs370319586; called by muse, mutect2
- CRYBG3 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1343724918; called by muse, mutect2, varscan2
- DYSF | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs754343148; ClinVar: uncertain significance; called by muse, mutect2
- FPR2 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60672422; called by muse, mutect2
- GPR156 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs555134314; called by muse, mutect2
- ITIH1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.051); catalogued as rs144224070, COSV56255906, COSV56257471; called by muse, mutect2
- KMT2D | c.11999G>T p.G4000V | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV56441169; called by muse, mutect2
- LILRA4 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1166654542, COSV52493659; called by muse, mutect2
- MARCHF10 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV60886062; called by muse, mutect2
- MS4A4E | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67518496; called by muse, mutect2
- MUC19 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV101373760; called by muse, mutect2
- MUC4 | c.10655C>T p.P3552L | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.722); catalogued as rs879709776, COSV100204564; called by muse, mutect2, varscan2
- MYF6 | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.811); catalogued as COSV57351299; called by muse, mutect2
- MYH1 | c.5106C>A p.S1702R | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV99875642; called by muse, mutect2
- MYH2 | c.3629G>T p.G1210V | Missense Mutation (SNP) | VAF 29/554 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV55445092; called by muse, mutect2
- PCDHA1 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.776); catalogued as rs1554117750; called by muse, mutect2
- PEX5L | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV55847502; called by muse, mutect2
- PRKCG | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 50/652 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54733942, COSV99668883; called by muse, mutect2
- PSG2 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 36/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754245034; called by muse, mutect2
- RGS21 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 50/450 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs372878348; called by muse, mutect2, varscan2
- RNF10 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1021762197; called by muse, mutect2
- STAG1 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 46/491 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV52604588; called by muse, mutect2
- TCTN2 | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.792); catalogued as rs1304326508; called by muse, mutect2
- TM4SF20 | c.344T>C p.M115T | Missense Mutation (SNP) | VAF 30/357 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1275005197; called by muse, mutect2
- TRIM51 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV99792104; called by muse, mutect2
- TSHZ3 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53668881, COSV99552976; called by muse, mutect2
- UNC80 | c.5435G>T p.W1812L | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV55891922; called by muse, mutect2
- WDPCP | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 28/433 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs985656097; called by muse, mutect2
- ABCD1 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ACRBP | c.1214T>A p.V405D | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, varscan2
- ACSS3 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 17/537 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ADAMTS17 | c.2629T>A p.C877S | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADGRB3 | c.3285C>A p.A1095= | Splice Region (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- ADGRL3 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- ANKRD17 | c.6478C>A p.P2160T | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2
- ANKRD17 | c.3158A>T p.Q1053L | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- ANKRD50 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 20/422 reads (5%) | called by muse, mutect2
- ANO4 | c.1864C>A p.P622T (on ENST00000392977 / NM_001286615.2; = p.P587T on NM_178826.4) | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANO4 | c.1865C>G p.P622R (on ENST00000392977 / NM_001286615.2; = p.P587R on NM_178826.4) | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANTXR1 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 28/700 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- APOOL | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.28); called by muse, mutect2
- ARHGAP24 | c.1855C>T p.R619* (on ENST00000395184 / NM_001025616.3; = p.R526* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- ASCC3 | c.4952G>T p.W1651L | Missense Mutation (SNP) | VAF 24/642 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BACH2 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 19/383 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- BIVM-ERCC5 | c.2814A>T p.E938D | Missense Mutation (SNP) | VAF 11/355 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- BPI | c.1295T>A p.L432Q (on ENST00000262865; = p.L428Q on NM_001725.3) | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRWD3 | c.3907G>T p.D1303Y | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- BSG | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- CACNA1S | c.4261G>T p.D1421Y | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNG8 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2
- CADPS | c.1850A>G p.Q617R | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CAPN9 | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- CASP8AP2 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 17/339 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2
- CCDC136 | c.1496A>G p.K499R | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC166 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- CCR4 | c.278C>G p.P93R | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD33 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CDCA2 | c.2417G>A p.S806N | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2
- CEACAM21 | c.848C>A p.P283H (on ENST00000401445 / NM_001098506.4; = p.P282H on NM_033543.6) | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CEP164 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHAT | c.1994A>G p.E665G | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2
- CHL1 | c.2319G>T p.M773I (on ENST00000397491 / NM_001253387.1; = p.M789I on NM_006614.4) | Missense Mutation (SNP) | VAF 57/549 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CHRNA4 | c.105C>G p.H35Q | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CLVS2 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CREB3L2 | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CRYGD | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.724); called by muse, mutect2
- EDN3 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2
- EFL1 | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- ELF3 | c.974_980del p.T325Rfs*3 | Frame Shift Del (DEL) | VAF 5/61 reads (8%) | called by mutect2, pindel
- EXOC4 | c.2425G>T p.D809Y | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EYS | c.1955G>T p.C652F | Missense Mutation (SNP) | VAF 47/760 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- FAM171A1 | c.582C>G p.N194K | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- FAN1 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FZD3 | c.957G>T p.W319C | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRA6 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 52/718 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- GABRG1 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- GK5 | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2
- GLG1 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2
- GNL2 | c.2086G>T p.V696L | Missense Mutation (SNP) | VAF 25/444 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2
- GPATCH8 | c.2770A>G p.K924E | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- GPR119 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- GRM7 | c.913G>T p.V305F | Missense Mutation (SNP) | VAF 43/497 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- GUCY2D | c.1685T>A p.L562Q | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAO2 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 18/524 reads (3%) | called by muse, mutect2
- HEATR5B | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2
- HEPACAM | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.089); called by muse, mutect2
- HMCN1 | c.8416C>T p.P2806S | Missense Mutation (SNP) | VAF 29/419 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- HPS5 | c.1186G>T p.D396Y (on ENST00000349215 / NM_181507.2; = p.D282Y on NM_007216.4) | Missense Mutation (SNP) | VAF 40/533 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- IL32 | c.200C>G p.A67G (on ENST00000396890 / NM_001308078.4; = p.A21G on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.149); called by muse, mutect2
- JADE2 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNK9 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 21/393 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2
- KIF21A | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- KIR3DL2 | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2
- KNL1 | c.6029T>A p.V2010D (on ENST00000346991 / NM_170589.5; = p.V1984D on NM_144508.5) | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KRT31 | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- LGR6 | c.2301G>T p.W767C (on ENST00000367278 / NM_001017403.1; = p.W715C on NM_021636.3) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRBA | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- LRRTM4 | c.404T>A p.L135H | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEE1 | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP1B | c.1670T>G p.V557G | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- MED12 | c.5827-1G>T p.X1943_splice | Splice Site (SNP) | VAF 18/419 reads (4%) | called by muse, mutect2
- MED13L | c.5705G>C p.G1902A | Missense Mutation (SNP) | VAF 22/696 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MED24 | c.1776G>T p.W592C | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- MORC3 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- MROH2B | c.552C>G p.D184E | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTA1 | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.098); called by muse, mutect2
- MUC19 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 17/276 reads (6%) | called by muse, mutect2
- MYH2 | c.3628G>T p.G1210W | Missense Mutation (SNP) | VAF 31/554 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NTN1 | c.1482C>A p.D494E | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); called by muse, mutect2
- OBSL1 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- OR2Z1 | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- OR8H1 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.119); called by muse, mutect2
- OR8H3 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OTOGL | c.6388A>T p.M2130L (on ENST00000547103; = p.M2121L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2
- P2RY12 | c.415T>A p.L139M | Missense Mutation (SNP) | VAF 56/714 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2
- PCDH11X | c.2834A>C p.Q945P | Missense Mutation (SNP) | VAF 62/742 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHA1 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.467); called by muse, mutect2
- PHACTR3 | c.893A>T p.H298L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- PIK3C2B | c.3905C>T p.A1302V | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PNPLA8 | c.1879-2A>G p.X627_splice | Splice Site (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- PPP6R3 | c.2570+1G>C p.X857_splice (on ENST00000393800 / NM_001352375.2; = p.X777_splice on NM_018312.5) | Splice Site (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- PRSS56 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- PTPRC | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 20/564 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.856); called by muse, mutect2
- PTPRZ1 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 29/420 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.028); called by muse, mutect2
- RASGRP2 | c.59G>C p.C20S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2
- RCVRN | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- REG1B | c.433+4A>T | Splice Region (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- RHOD | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- RPL10 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 45/472 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2
- RYR1 | c.2386C>A p.H796N | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- SALL2 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SENP2 | c.1314C>A p.F438L | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- SIRPG | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- SVEP1 | c.9154T>A p.W3052R | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TENM1 | c.7847C>A p.T2616N | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TLR4 | c.2226C>G p.I742M (on ENST00000355622 / NM_138554.5; = p.I702M on NM_003266.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TMX1 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAPPC9 | c.3305G>T p.C1102F | Missense Mutation (SNP) | VAF 22/371 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.081); called by muse, mutect2
- TRIM59 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 36/409 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2
- TSHZ3 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 15/207 reads (7%) | called by muse, mutect2
- TTN | c.38323G>C p.D12775H (on ENST00000591111; = p.D5351H on NM_003319.4) | Missense Mutation (SNP) | VAF 20/626 reads (3%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TXLNB | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 38/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- TXLNB | c.1011C>A p.N337K | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.268); called by muse, mutect2
- UGT2B11 | c.100A>C p.S34R | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UGT2B28 | c.1225A>G p.K409E | Missense Mutation (SNP) | VAF 26/527 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- UIMC1 | c.1378A>T p.R460* | Nonsense Mutation (SNP) | VAF 19/318 reads (6%) | called by muse, mutect2
- ULK4 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 23/305 reads (8%) | called by muse, mutect2
- USP3 | c.625A>T p.R209W | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP6NL | c.1526G>C p.R509P | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- VN1R5 | c.525C>A p.N175K | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- WNT10B | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 23/321 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2
- WWP1 | c.2065A>G p.K689E | Missense Mutation (SNP) | VAF 32/407 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF223 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- ZNF777 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ZNF850 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPP | c.918G>T p.L306= | Silent (SNP) | VAF 30/620 reads (5%) | called by muse, mutect2
- ANO2 | c.693G>T p.S231= (on ENST00000356134 / NM_001278597.3; = p.S235= on NM_001278596.3) | Silent (SNP) | VAF 27/400 reads (7%) | catalogued as rs746073538, COSV100502077, COSV59033970; called by muse, mutect2
- APOB | c.7537C>A p.R2513= | Silent (SNP) | VAF 21/306 reads (7%) | catalogued as CM910035; called by muse, mutect2
- ATP13A1 | c.1429C>T p.L477= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- ATP4A | c.450G>T p.V150= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- BMPR2 | c.375C>A p.V125= | Silent (SNP) | VAF 31/643 reads (5%) | called by muse, mutect2
- BMS1 | c.3069T>A p.I1023= | Silent (SNP) | VAF 21/509 reads (4%) | called by muse, mutect2
- CCN3 | c.588A>T p.G196= | Silent (SNP) | VAF 20/249 reads (8%) | catalogued as rs779711912; called by muse, mutect2
- CEP128 | c.1929C>T p.I643= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as rs1313804384; called by muse, mutect2
- CHST11 | c.747C>A p.T249= | Silent (SNP) | VAF 14/227 reads (6%) | called by muse, mutect2
- CNTN5 | c.1260G>T p.T420= | Silent (SNP) | VAF 26/418 reads (6%) | catalogued as COSV54307004; called by muse, mutect2
- CNTN5 | c.3265T>C p.L1089= | Silent (SNP) | VAF 20/573 reads (3%) | catalogued as COSV99679413; called by muse, mutect2
- CRYBG1 | c.273G>T p.A91= | Silent (SNP) | VAF 27/392 reads (7%) | catalogued as rs9486348; called by muse, mutect2
- DENND2A | c.2142C>A p.I714= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV52049651; called by muse, mutect2
- DLC1 | c.930C>A p.V310= | Silent (SNP) | VAF 23/470 reads (5%) | called by muse, mutect2
- DYNC2H1 | c.5643A>G p.R1881= | Silent (SNP) | VAF 20/428 reads (5%) | called by muse, mutect2
- FAM83C | c.885G>A p.R295= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- FMNL3 | c.357C>A p.T119= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- FMR1NB | c.709A>C p.R237= | Silent (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- FOXP2 | c.237T>C p.S79= | Silent (SNP) | VAF 56/873 reads (6%) | called by muse, mutect2
- GPHN | c.1782C>T p.I594= (on ENST00000315266 / NM_001377519.1; = p.I627= on NM_020806.5) | Silent (SNP) | VAF 57/874 reads (7%) | called by muse, mutect2
- GPR32 | c.381C>A p.A127= | Silent (SNP) | VAF 19/484 reads (4%) | called by muse, mutect2
- HMCN2 | c.10671C>A p.L3557= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
- IQGAP3 | c.2199T>C p.F733= | Silent (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- KCNJ4 | c.291G>C p.G97= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1276342865; called by muse, mutect2, varscan2
- KIAA1210 | c.2118A>G p.E706= | Silent (SNP) | VAF 28/393 reads (7%) | called by muse, mutect2
- LMAN2 | c.69C>T p.L23= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100288389; called by muse, mutect2
- LTB4R2 | c.783G>T p.V261= (on ENST00000528054; = p.V230= on NM_019839.5) | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- LY6G6E | c.75G>A p.R25= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- MGAM2 | c.4959C>A p.I1653= | Silent (SNP) | VAF 15/279 reads (5%) | called by muse, mutect2
- MYH2 | c.528G>T p.L176= | Silent (SNP) | VAF 32/694 reads (5%) | catalogued as COSV55448553; called by muse, mutect2
- MYH6 | c.429G>A p.R143= | Silent (SNP) | VAF 17/325 reads (5%) | called by muse, mutect2
- NEB | c.3318A>G p.Q1106= | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- NLRP1 | c.4188G>T p.V1396= (on ENST00000572272 / NM_033004.4; = p.V1352= on NM_014922.5) | Silent (SNP) | VAF 17/300 reads (6%) | called by muse, mutect2
- OR51E1 | c.276C>A p.S92= | Silent (SNP) | VAF 16/338 reads (5%) | catalogued as COSV67809838; called by muse, mutect2
- PCDH8 | c.2799G>T p.G933= | Silent (SNP) | VAF 20/452 reads (4%) | called by muse, mutect2
- PCNT | c.6489C>T p.I2163= | Silent (SNP) | VAF 32/678 reads (5%) | catalogued as rs1413843678, COSV100855341; called by muse, mutect2
- PEG3 | c.1284G>A p.V428= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- PRKCG | c.1770G>T p.L590= | Silent (SNP) | VAF 35/465 reads (8%) | called by muse, mutect2
- PTGER4 | c.1416G>A p.L472= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- PTPDC1 | c.663G>T p.R221= (on ENST00000375360 / NM_177995.3; = p.R273= on NM_152422.4) | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- RNF150 | c.159G>T p.P53= | Silent (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- RTBDN | c.207A>G p.T69= (on ENST00000393233 / NM_001270444.1; = p.T101= on NM_031429.2) | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs1332495356; called by muse, mutect2
- SPDYE1 | c.798C>A p.P266= | Silent (SNP) | VAF 43/510 reads (8%) | catalogued as COSV99324053; called by muse, mutect2
- SPRR2D | c.33C>A p.P11= | Silent (SNP) | VAF 17/562 reads (3%) | called by muse, mutect2
- SSTR1 | c.528A>T p.V176= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- TAS2R5 | c.483C>T p.P161= | Silent (SNP) | VAF 30/228 reads (13%) | catalogued as rs1019695263; called by muse, mutect2, varscan2
- TENM2 | c.1155C>A p.L385= (on ENST00000518659 / NM_001122679.2; = p.L194= on NM_001080428.3) | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV69140842; called by muse, mutect2
- TENT5D | c.1059G>T p.P353= | Silent (SNP) | VAF 15/221 reads (7%) | catalogued as COSV57635629; called by muse, mutect2
- TTC21B | c.2814G>A p.L938= | Silent (SNP) | VAF 26/888 reads (3%) | catalogued as rs991068123, COSV54635278; called by muse, mutect2
- VSIG10 | c.849G>A p.S283= | Silent (SNP) | VAF 18/328 reads (5%) | catalogued as rs1048910257; called by muse, mutect2
- YIPF3 | c.93A>T p.S31= | Silent (SNP) | VAF 13/376 reads (3%) | called by muse, mutect2
- ZNF208 | c.2934T>C p.C978= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- ZNF33A | c.1896G>T p.G632= (on ENST00000458705 / NM_006974.3; = p.G633= on NM_006954.2) | Silent (SNP) | VAF 28/342 reads (8%) | called by muse, mutect2
- ZNF518B | c.288C>T p.P96= | Silent (SNP) | VAF 33/514 reads (6%) | catalogued as COSV100456518; called by muse, mutect2
- ZNF536 | c.3024C>T p.F1008= | Silent (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- ATP6V0A2 | c.1038+73A>G | Intron (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- CPLANE1 | c.*1815T>A | 3'UTR (SNP) | VAF 33/290 reads (11%) | called by muse, mutect2, varscan2
- FBRS | c.-113C>T | 5'UTR (SNP) | VAF 8/68 reads (12%) | catalogued as rs1195305667; called by muse, varscan2
- FMR1 | c.*673G>C | 3'UTR (SNP) | VAF 42/440 reads (10%) | called by muse, mutect2
- GATM | c.70-441T>A | Intron (SNP) | VAF 16/458 reads (3%) | called by muse, mutect2
- HSP90AB3P | n.29A>T | RNA (SNP) | VAF 19/194 reads (10%) | called by muse, mutect2
- IGHV3-20 | c.-18G>A | 5'UTR (SNP) | VAF 21/356 reads (6%) | called by muse, mutect2
- KIF1A | c.2555+1018C>A | Intron (SNP) | VAF 12/128 reads (9%) | catalogued as COSV57494555; called by muse, varscan2
- NOS3 | c.1752+1403C>T | Intron (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- OR2M1P | n.272C>A | RNA (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- SLC25A36 | c.385+3735A>G | Intron (SNP) | VAF 26/572 reads (5%) | called by muse, mutect2
- TNNI3 | c.372+43G>C | Intron (SNP) | VAF 15/225 reads (7%) | catalogued as rs752348828; called by muse, mutect2
- TTN | c.10360+2929G>C | Intron (SNP) | VAF 42/309 reads (14%) | catalogued as COSV59993112; called by muse, mutect2, varscan2
- WT1 | chr11:32439433 C>A | 5'Flank (SNP) | VAF 16/331 reads (5%) | called by muse, mutect2
- ZFAND5 | c.-126G>T | 5'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
